Gene-level copy-number profile of tumor specimen TCGA-AA-3544-01A from TCGA case TCGA-AA-3544, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 68.3 years (24,959 days).
Specimen TCGA-AA-3544-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.07c10a71-e945-4796-a3e0-3d48ec7e51f1.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AA-3544-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/4d642e7c-6d45-4324-9d1a-276304ba7711

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 9,933; copy number 2: 39,757; copy number 3: 7,227; copy number 4: 1,268; copy number 5: 1,558; copy number 6: 62; copy number 9: 6.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AA-3544-01A-01D-0819-01): tumor purity 0.73, ploidy 2.19, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:186,486,253–186,695,287, 4 genes (within-gene range 0–1): ZC3H15, DPRXP1, ITGAV, AC017101.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,626 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:38,273,587–38,311,808, 6 genes, copy number 9: TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1.
- chr8:41,261,962–43,674,591, 80 genes, copy number 5 (broad region; genes not listed).
- chr8:48,710,789–145,066,685, 1,478 genes, copy number 5 (within-gene range 1–5) (broad region; genes not listed).
- chr14:22,155,079–22,513,998, 62 genes, copy number 6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 7,546. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
